Somatic mutation profile of tumor specimen HTMCP-03-06-02406-01A (aliquot HTMCP-03-06-02406-01A-01D-10409) from CGCI case HTMCP-03-06-02406, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3.
Specimen HTMCP-03-06-02406-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad8191b0-ba51-4d77-b5f3-c749570a28e9.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02406-10A (Blood Derived Normal), aliquot HTMCP-03-06-02406-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b349b942-a35f-4c89-a072-b593431745d6

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Splice Site 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3019G>C p.G1007R | Missense Mutation (SNP) | VAF 21/185 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.797); catalogued as COSV55882140; called by muse, mutect2, varscan2
- AFM | c.1720G>A p.A574T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs566545619, COSV56922231; called by muse, mutect2, varscan2
- CBY2 | c.472C>A p.H158N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs1054531612; called by muse, mutect2, varscan2
- FCGR2B | c.213C>G p.C71W | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52682984; called by muse, mutect2
- GUCY2F | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs771847070, COSV54306906; called by muse, mutect2, varscan2
- MED24 | c.2630G>A p.R877Q | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.968); catalogued as rs779300635; called by muse, mutect2, varscan2
- APOBEC3G | c.15C>T p.F5= | Splice Region (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- ASPM | c.8821-2A>G p.X2941_splice | Splice Site (SNP) | VAF 19/103 reads (18%) | called by muse, mutect2, varscan2
- CACNA1E | c.3302A>G p.E1101G | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- CYLD | c.92C>T p.T31I | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA2026 | c.977A>G p.Y326C | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); called by muse, mutect2
- MAP2 | c.4120G>A p.D1374N | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SERPINI1 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.041); called by muse, mutect2
- BRSK1 | c.2046C>T p.S682= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs372118776; called by muse, mutect2, varscan2
- ERC2 | c.1368G>A p.K456= | Silent (SNP) | VAF 28/104 reads (27%) | catalogued as rs530392914; called by muse, mutect2, varscan2
- HECTD1 | c.1639C>T p.L547= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as rs769574276; called by muse, mutect2, varscan2
- PXDN | c.3396G>A p.S1132= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as rs572948126, COSV53236702; ClinVar: likely benign; called by muse, mutect2, varscan2
- CR381670.2 | n.231C>G | RNA (SNP) | VAF 16/263 reads (6%) | called by muse, mutect2
